Somatic mutation profile of tumor specimen TCGA-21-1070-01A (aliquot TCGA-21-1070-01A-01W-0782-08) from TCGA case TCGA-21-1070, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.0 years (22,273 days).
Specimen TCGA-21-1070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 746264dc-6a4f-4285-8b42-7e6397809fd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1070-11A (Solid Tissue Normal), aliquot TCGA-21-1070-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/106138be-f1e6-48a1-b631-a1681a4a3eb7

The open-access MAF lists 554 somatic variants for this specimen: 438 protein-altering or splice-affecting, 98 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 372, Silent 98, Nonsense Mutation 30, Splice Site 16, Frame Shift Del 12, RNA 9, Intron 8, Frame Shift Ins 2, Splice Region 2, Translation Start Site 2, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1216-16_1216-1del p.X406_splice | Splice Site (DEL) | VAF 28/139 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 85/337 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1266G>A p.R422= | Splice Region (SNP) | VAF 53/231 reads (23%) | catalogued as COSV59385488; called by muse, mutect2, varscan2
- ABCA13 | c.9779C>A p.S3260Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV71286429; called by muse, mutect2, varscan2
- ABCC2 | c.1032-1G>T p.X344_splice | Splice Site (SNP) | VAF 484/1668 reads (29%) | catalogued as COSV64970586, COSV64970782; called by muse, mutect2, varscan2
- ABCG8 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 216/492 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55392462; called by muse, mutect2, varscan2
- AC105001.2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59108942; called by muse, mutect2, varscan2
- AC105001.2 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59108951; called by muse, mutect2, varscan2
- ACER2 | c.640T>A p.W214R | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820673; called by muse, mutect2, varscan2
- ACTC1 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV51758673; called by muse, mutect2, varscan2
- ACTL6A | c.476+1G>T p.X159_splice | Splice Site (SNP) | VAF 219/1347 reads (16%) | catalogued as COSV66998876; called by muse, mutect2, varscan2
- ACTN4 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53145221; called by muse, mutect2, varscan2
- ACTRT1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 197/1305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419229, COSV64419284; called by muse, varscan2
- ACVR1C | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54645602; called by muse, mutect2, varscan2
- ADAM18 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs1407646764, COSV55846408; called by muse, mutect2, varscan2
- ADAM23 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213024; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3038G>T p.R1013M | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99717632; called by muse, mutect2, varscan2
- ADGRE3 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.501); catalogued as COSV53730066; called by muse, mutect2, varscan2
- ALPK1 | c.2494T>A p.S832T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV51584211; called by muse, varscan2
- ALPK1 | c.2495C>A p.S832Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.467); catalogued as COSV51584218, COSV51589939; called by muse, varscan2
- AMER1 | c.2088G>C p.R696S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV57654356, COSV57659417; called by muse, mutect2, varscan2
- ANAPC5 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1475551358, COSV55842462; called by muse, mutect2, varscan2
- ANK3 | c.12431G>C p.R4144T (on ENST00000280772 / NM_001320874.2; = p.R665T on NM_001149.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV55054205; called by muse, mutect2
- ANKRD35 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV62910111; called by muse, mutect2, varscan2
- ANO4 | c.1900C>A p.L634I (on ENST00000392977 / NM_001286615.2; = p.L599I on NM_178826.4) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.733); catalogued as rs1405028889, COSV54593239; called by muse, mutect2, varscan2
- ANXA10 | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV63738200; called by muse, mutect2, varscan2
- APLF | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58144203; called by muse, mutect2, varscan2
- AREL1 | c.646C>G p.H216D | Missense Mutation (SNP) | VAF 125/553 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV62666202, COSV62666697; called by muse, varscan2
- ARHGAP12 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60962777; called by muse, mutect2, varscan2
- ARMC4 | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV100536672, COSV59461933; called by muse, mutect2, varscan2
- ASB12 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62856598; called by muse, mutect2, varscan2
- ASB9 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66851627; called by muse, mutect2, varscan2
- ASTN2 | c.1714C>A p.L572M (on ENST00000313400 / NM_001365069.1; = p.L521M on NM_014010.5) | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57771522; called by muse, mutect2, varscan2
- ATF2 | c.1432A>T p.T478S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51368856; called by muse, mutect2, varscan2
- ATG2B | c.4843-1G>T p.X1615_splice | Splice Site (SNP) | VAF 12/142 reads (8%) | catalogued as COSV55890093; called by muse, mutect2
- ATP8B4 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV52713811; called by muse, mutect2, varscan2
- ATRX | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 98/396 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV64875138; called by muse, mutect2, varscan2
- BARD1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53611217; called by muse, mutect2
- BBS7 | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV52655955; called by muse, mutect2, varscan2
- BBX | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs771614227, COSV57882938; called by muse, mutect2, varscan2
- BCORL1 | c.2045C>G p.S682C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV54394717; called by muse, mutect2, varscan2
- BIRC6 | c.13096C>G p.Q4366E | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs962851082, COSV70198326; called by muse, mutect2
- BMPR1A | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 30/455 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.315); catalogued as COSV63135099; called by muse, mutect2
- BPIFB4 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64951062; called by muse, mutect2, varscan2
- BPIFC | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55912042; called by muse, mutect2, varscan2
- BRINP3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748757778, COSV66531106; called by muse, mutect2, varscan2
- BRINP3 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs779280815, COSV66521061; called by muse, mutect2, varscan2
- BRPF1 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV57352528; called by muse, mutect2, varscan2
- BRWD3 | c.1746C>A p.H582Q | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64747017; called by muse, mutect2, varscan2
- BTLA | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV57938158, COSV57938330; called by muse, mutect2, varscan2
- BUB1B | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55011888; called by muse, mutect2, varscan2
- C1orf94 | c.1225C>A p.P409T (on ENST00000488417 / NM_001134734.2; = p.P219T on NM_032884.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV64913793; called by muse, mutect2
- C7 | c.2236C>A p.H746N | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); catalogued as COSV100496768, COSV57473507; called by muse, mutect2, varscan2
- C9 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54676221; called by muse, mutect2, varscan2
- C9orf131 | c.2688C>G p.S896R | Missense Mutation (SNP) | VAF 105/556 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV56610205, COSV56610678; called by muse, mutect2, varscan2
- C9orf78 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204121, COSV59613145; called by muse, mutect2, varscan2
- CACNA1F | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV59904061; called by muse, mutect2
- CADM2 | c.943+1G>T p.X315_splice (on ENST00000407528 / NM_001167674.2; = p.X317_splice on NM_153184.4) | Splice Site (SNP) | VAF 80/248 reads (32%) | catalogued as COSV67369529; called by muse, mutect2, varscan2
- CARD6 | c.1023G>T p.R341S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54564618, COSV54565761; called by muse, mutect2, varscan2
- CARMIL3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs370361215; called by muse, mutect2, varscan2
- CASR | c.548T>A p.F183Y | Missense Mutation (SNP) | VAF 142/584 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV56136730; called by muse, mutect2, varscan2
- CCDC85A | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68149878; called by muse, mutect2, varscan2
- CCNB3 | c.3957C>G p.Y1319* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV52072477; called by muse, mutect2, varscan2
- CD164L2 | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV64995628; called by muse, mutect2
- CD207 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV69651970; called by mutect2, varscan2
- CD207 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV69651972; called by muse, mutect2, varscan2
- CDH18 | c.2095C>G p.P699A | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56916381, COSV56922528; called by muse, mutect2, varscan2
- CDH23 | c.7568C>G p.P2523R | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56458782, COSV56462271; called by muse, mutect2, varscan2
- CDK18 | c.760A>T p.S254C (on ENST00000506784 / NM_212503.3; = p.S224C on NM_002596.4) | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV63727243; called by muse, mutect2, varscan2
- CEACAM20 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 180/686 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57601464; called by muse, mutect2, varscan2
- CEP89 | c.1566-2A>T p.X522_splice | Splice Site (SNP) | VAF 56/232 reads (24%) | catalogued as rs993705365, COSV59863685; called by muse, mutect2, varscan2
- CERKL | c.884G>C p.G295A (on ENST00000339098 / NM_001030311.2; = p.G269A on NM_201548.5) | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59206708; called by muse, mutect2
- CERS2 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777928416, COSV54981110; called by muse, mutect2, varscan2
- CFAP61 | c.1714A>G p.K572E | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55626633; called by muse, mutect2, varscan2
- CFAP61 | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55626643; called by muse, varscan2
- CHAT | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60323775; called by muse, mutect2, varscan2
- CHD9 | c.5378A>T p.Q1793L | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54609603; called by muse, mutect2, varscan2
- CHRNA1 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV53682648; called by muse, mutect2, varscan2
- CHRNA4 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV64719148; called by muse, mutect2, varscan2
- CITED2 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100863130, COSV62726395; called by muse, mutect2, varscan2
- CLPTM1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV61611687; called by muse, mutect2, varscan2
- COL12A1 | c.3767A>C p.H1256P | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59394270; called by muse, mutect2
- COL24A1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204714428, COSV65305104, COSV65312329; called by muse, mutect2, varscan2
- COL24A1 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993309, COSV65305107; called by muse, mutect2
- COX7A2L | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV52243040; called by muse, mutect2, varscan2
- CP | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 118/560 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52830172; called by muse, mutect2, varscan2
- CPN1 | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 178/868 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV64942194; called by muse, mutect2, varscan2
- CPN1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV64942195; called by muse, mutect2, varscan2
- CPS1 | c.2688-1G>A p.X896_splice | Splice Site (SNP) | VAF 18/109 reads (17%) | catalogued as COSV51808119; called by muse, mutect2, varscan2
- CSMD2 | c.10129G>T p.G3377C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53904073; called by muse, mutect2, varscan2
- CSMD2 | c.10128G>T p.K3376N | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99587419; called by muse, mutect2, varscan2
- CSMD2 | c.7654A>T p.K2552* | Nonsense Mutation (SNP) | VAF 68/232 reads (29%) | catalogued as COSV53904093; called by muse, mutect2, varscan2
- CSMD2 | c.1484G>T p.W495L | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV53904116; called by muse, mutect2
- CSMD3 | c.9824G>A p.G3275E (on ENST00000297405 / NM_001363185.1; = p.G3106E on NM_052900.3) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV52158742, COSV99835522; called by muse, mutect2, varscan2
- CSMD3 | c.9823G>T p.G3275W (on ENST00000297405 / NM_001363185.1; = p.G3106W on NM_052900.3) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52276628; called by muse, mutect2, varscan2
- CSMD3 | c.4009G>T p.G1337W (on ENST00000297405 / NM_001363185.1; = p.G1233W on NM_052900.3) | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99828549; called by muse, mutect2, varscan2
- CSMD3 | c.3281C>A p.T1094K (on ENST00000297405 / NM_001363185.1; = p.T990K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52158763; called by muse, mutect2, varscan2
- CUL4B | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as COSV60686790; called by muse, mutect2, varscan2
- CYP2F1 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV58527224; called by muse, mutect2, varscan2
- CYSLTR1 | c.629C>A p.T210K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV64819942; called by muse, mutect2, varscan2
- DACT1 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs768116433, COSV60020451; called by muse, mutect2, varscan2
- DCBLD1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 82/449 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV51640178; called by muse, mutect2, varscan2
- DCBLD2 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 181/961 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58788995; called by muse, mutect2, varscan2
- DCHS1 | c.3403G>T p.G1135* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV55034308; called by muse, mutect2, varscan2
- DHX30 | c.519T>G p.I173M (on ENST00000445061 / NM_138615.3; = p.I134M on NM_014966.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV62394271, COSV62396183; called by muse, varscan2
- DLD | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52737671; called by muse, mutect2, varscan2
- DLGAP1 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as COSV59798716; called by muse, mutect2, varscan2
- DMBT1 | c.3172G>T p.D1058Y (on ENST00000338354 / NM_001377530.1; = p.D559Y on NM_004406.3) | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57541397; called by muse, mutect2, varscan2
- DMD | c.11014+1G>T p.X3672_splice | Splice Site (SNP) | VAF 48/206 reads (23%) | catalogued as COSV58905629; called by muse, mutect2, varscan2
- DNAH3 | c.7615G>A p.E2539K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54516750; called by muse, mutect2, varscan2
- DNAH3 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1173336641; called by muse, mutect2
- DNAH7 | c.7432A>G p.I2478V | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56760786; called by muse, mutect2, varscan2
- DNAH7 | c.4956G>T p.M1652I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV56760795; called by muse, mutect2, varscan2
- DNAJB2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV60676419, COSV60677461; called by muse, mutect2, varscan2
- DPH2 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV52543227; called by muse, mutect2, varscan2
- DPRX | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV64949386; called by muse, mutect2, varscan2
- DPYSL5 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56511034; called by muse, mutect2
- DRP2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 81/673 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as COSV65809162; called by muse, mutect2, varscan2
- DSC1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57144592; called by muse, mutect2, varscan2
- DSP | c.7389G>T p.K2463N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65792389; called by muse, mutect2, varscan2
- DST | c.13109G>T p.C4370F (on ENST00000361203 / NM_001374722.1; = p.C1958F on NM_015548.5) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55009774; called by muse, mutect2, varscan2
- DUSP13 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57814134; called by muse, mutect2, varscan2
- DYSF | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50269067, COSV50300200; called by muse, mutect2, varscan2
- EMG1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54641717; called by muse, mutect2, varscan2
- ENPEP | c.2391G>T p.E797D | Missense Mutation (SNP) | VAF 114/311 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV54449783; called by muse, mutect2, varscan2
- ENPP1 | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931862; called by muse, mutect2, varscan2
- EPHA1 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.994); catalogued as COSV51970621; called by muse, mutect2, varscan2
- EPS15 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV65541788; called by muse, mutect2, varscan2
- ETV5 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 94/369 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60501234; called by muse, mutect2, varscan2
- EVC2 | c.2389G>T p.D797Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV60391930; called by muse, mutect2, varscan2
- FAM110B | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV64064672; called by muse, mutect2, varscan2
- FAM131B | c.615A>T p.E205D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58369254; called by muse, mutect2, varscan2
- FAM135A | c.3748C>G p.L1250V (on ENST00000370479 / NM_001351599.1; = p.L1037V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52050312; called by muse, mutect2, varscan2
- FASTKD3 | c.288T>G p.N96K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.024); catalogued as COSV52942961; called by muse, mutect2, varscan2
- FBN3 | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54458753; called by muse, mutect2, varscan2
- FBXO11 | c.287A>G p.N96S (on ENST00000403359 / NM_001190274.2; = p.N12S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV57018641; called by muse, mutect2
- FCGBP | c.6529G>A p.V2177M | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1181929438, COSV99661473; called by muse, mutect2
- FER1L5 | c.4755C>A p.F1585L (on ENST00000623019; = p.F1558L on NM_001293083.2) | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV67606012; called by muse, mutect2, varscan2
- FGD1 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64308291, COSV64308548; called by muse, mutect2, varscan2
- FLG2 | c.1792T>A p.S598T | Missense Mutation (SNP) | VAF 77/492 reads (16%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.616); catalogued as COSV66168103, COSV66173151; called by muse, mutect2, varscan2
- FLT1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV56725656; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52545935; called by muse, mutect2, varscan2
- FREM1 | c.4136C>A p.P1379H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101084023; called by muse, mutect2, varscan2
- FRMPD1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs550566906, COSV66700934; called by muse, mutect2
- FSCB | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV61217652; called by muse, mutect2, varscan2
- GALNT1 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52452057; called by muse, mutect2
- GAPVD1 | c.2695C>T p.R899* (on ENST00000394104; = p.R926* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV52919951; called by muse, mutect2, varscan2
- GDF3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61712234, COSV61713136; called by muse, mutect2, varscan2
- GFRAL | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 377/1473 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61230371; called by muse, mutect2, varscan2
- GLYATL2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1217238835, COSV54849720; called by muse, varscan2
- GMNN | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV57776767; called by muse, mutect2, varscan2
- GNB4 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709192; called by muse, mutect2, varscan2
- GNG5 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV55362035; called by muse, mutect2, varscan2
- GOLIM4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 261/1326 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV58329325; called by muse, mutect2, varscan2
- GPD1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 90/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761342764, COSV56547852; called by muse, mutect2, varscan2
- GPR143 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV66632290; called by muse, mutect2, varscan2
- GPR31 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.166); catalogued as rs1242318594, COSV64761353; called by muse, mutect2, varscan2
- GPR65 | c.286A>C p.M96L | Missense Mutation (SNP) | VAF 127/498 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50862582; called by muse, mutect2, varscan2
- GRAMD1C | c.1248G>T p.L416F | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV63982571; called by muse, mutect2, varscan2
- GRAMD1C | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV63982575, COSV63982884; called by muse, mutect2, varscan2
- GRIA1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV53599215; called by muse, mutect2, varscan2
- GRIA3 | c.2431G>T p.D811Y | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV99989428; called by muse, mutect2
- GRM4 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV65212587; called by muse, mutect2, varscan2
- GSG1L | c.995G>T p.*332Lext*35 (on ENST00000447459 / NM_001109763.2; = p.*177Lext*35 on NM_144675.2) | Nonstop Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV66577856; called by muse, mutect2, varscan2
- GTF3C2 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as COSV53126090; called by muse, mutect2, varscan2
- GUCY2F | c.2472G>T p.M824I | Missense Mutation (SNP) | VAF 163/1009 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54300897; called by muse, mutect2, varscan2
- GUCY2F | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV54300908; called by muse, mutect2, varscan2
- H2AC16 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58899781; called by muse, mutect2, varscan2
- HAO1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV66491751; called by muse, mutect2, varscan2
- HCN1 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100298680, COSV57505727; called by muse, mutect2, varscan2
- HDAC9 | c.1439A>C p.Q480P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV67771666; called by muse, mutect2, varscan2
- HDAC9 | c.2767C>A p.L923I | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67769866; called by muse, mutect2, varscan2
- HERC2 | c.4574G>T p.C1525F | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV99871840; called by muse, mutect2, varscan2
- HGF | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55948188; called by muse, varscan2
- HRNR | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs1426884760, COSV64257054; called by muse, mutect2, varscan2
- HUWE1 | c.10582G>T p.V3528L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53342082, COSV53342708; called by muse, mutect2, varscan2
- IGFBP6 | c.573C>G p.D191E | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56857257; called by muse, mutect2, varscan2
- IGKV1-8 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs771866000; called by muse, mutect2, varscan2
- IGSF1 | c.1647-1G>C p.X549_splice | Splice Site (SNP) | VAF 31/118 reads (26%) | catalogued as COSV63837072; called by muse, mutect2, varscan2
- IGSF11 | c.938C>T p.S313F (on ENST00000393775 / NM_001015887.3; = p.S312F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/548 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61168681; called by muse, mutect2, varscan2
- IL20RA | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as COSV57357795; called by muse, mutect2, varscan2
- IPO9 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64233473; called by muse, mutect2, varscan2
- ISX | c.5G>T p.C2F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV58086301; called by muse, mutect2, varscan2
- ITGAD | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV66757684; called by muse, mutect2, varscan2
- KATNA1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768388071, COSV59502173; called by muse, mutect2, varscan2
- KATNIP | c.1742G>C p.G581A | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV55178865; called by muse, mutect2, varscan2
- KCNK10 | c.78C>A p.S26R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as COSV56643439; called by muse, mutect2, varscan2
- KCTD1 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV58685495; called by mutect2, varscan2
- KIF5C | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68480811; called by muse, mutect2, varscan2
- KLHL12 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63042710; called by muse, mutect2, varscan2
- KLHL22 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV61020605; called by muse, mutect2, varscan2
- KNG1 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53977298; called by muse, mutect2, varscan2
- LARGE2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV57652762; called by muse, mutect2, varscan2
- LDHB | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63364580; called by muse, mutect2, varscan2
- LIG4 | c.2602G>T p.D868Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV63596893, COSV63597587; called by muse, mutect2
- LILRA2 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV52190834; called by muse, mutect2, varscan2
- LMO7 | c.293A>G p.N98S (on ENST00000357063; = p.N113S on NM_005358.5) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751118448, COSV58534331; called by muse, mutect2, varscan2
- LRP1B | c.8945G>T p.C2982F | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771259326, COSV67199534; called by muse, mutect2, varscan2
- LRRIQ1 | c.3154G>T p.A1052S | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV67829494, COSV67834868; called by muse, mutect2, varscan2
- LSAMP | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.484); catalogued as COSV61286799; called by muse, mutect2, varscan2
- MAGEA4 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 18/129 reads (14%) | catalogued as COSV52341000, COSV52341324; called by muse, mutect2, varscan2
- MAK16 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV100659740; called by muse, mutect2
- MAN2B1 | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.217); catalogued as COSV55471487; called by muse, mutect2, varscan2
- MAP3K7 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65224183; called by muse, mutect2, varscan2
- MARF1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV60022512; called by muse, mutect2, varscan2
- MARK3 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53509428; called by muse, mutect2, varscan2
- MCTS1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV64892433; called by muse, mutect2
- MERTK | c.2897G>T p.G966V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV54934701, COSV99774278; called by muse, mutect2, varscan2
- MICU3 | c.1085+1G>A p.X362_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV58845600; called by muse, mutect2, varscan2
- MKRN3 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 38/281 reads (14%) | catalogued as COSV58809430; called by muse, mutect2, varscan2
- MLPH | c.1732A>T p.R578* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as COSV52819700; called by muse, mutect2, varscan2
- MMP20 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52775135; called by muse, mutect2, varscan2
- MMS22L | c.3500A>G p.Y1167C | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV51519980; called by muse, mutect2
- MMS22L | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV51519991; called by muse, mutect2, varscan2
- MROH2B | c.4266G>A p.W1422* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV68183115; called by muse, mutect2
- MROH2B | c.2545G>T p.G849C | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68183121; called by muse, mutect2, varscan2
- MROH2B | c.855C>A p.C285* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | catalogued as COSV68183125; called by muse, mutect2, varscan2
- MROH9 | c.901A>C p.I301L | Missense Mutation (SNP) | VAF 224/762 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63010917; called by muse, mutect2
- MS4A6E | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55726620; called by muse, mutect2, varscan2
- MTMR8 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs746078951, COSV66393358; called by muse, mutect2, varscan2
- MUC16 | c.24904C>A p.P8302T | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV67461200; called by muse, mutect2, varscan2
- MYCT1 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 44/481 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65891212; called by muse, mutect2
- MYH13 | c.5702G>T p.R1901L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52825992, COSV52837748, COSV99355915; called by muse, mutect2, varscan2
- MYH15 | c.4057G>T p.D1353Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56308400; called by muse, mutect2, varscan2
- MYL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV57406801; called by muse, mutect2, varscan2
- MYO18B | c.6716C>G p.S2239W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs192136611, COSV100123211, COSV59145660; called by muse, mutect2, varscan2
- MYO7B | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV67344334, COSV67346872; called by muse, mutect2, varscan2
- NALCN | c.5036T>A p.I1679K | Missense Mutation (SNP) | VAF 63/528 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51930749; called by muse, mutect2, varscan2
- NCKAP1L | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53205885; called by muse, mutect2, varscan2
- NCOR1 | c.4916A>G p.E1639G | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV51971600; called by muse, mutect2
- NCOR1 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 18/177 reads (10%) | catalogued as COSV51971624; called by muse, mutect2
- NEFM | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55331691; called by muse, mutect2, varscan2
- NELL1 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 132/576 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs765086921, COSV54236125, COSV54257333; called by muse, mutect2, varscan2
- NLRP3 | c.1395G>C p.W465C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV60223025; called by muse, mutect2
- NLRP4 | c.1990C>A p.H664N | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV56712228; called by muse, mutect2, varscan2
- NOTCH2 | c.5197G>T p.D1733Y | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56702819; called by muse, mutect2, varscan2
- NOTCH2 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863224; called by muse, mutect2, varscan2
- NPY2R | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 83/383 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61527922; called by muse, mutect2, varscan2
- NR1H4 | c.466G>T p.G156W (on ENST00000551379 / NM_001206993.2; = p.G146W on NM_005123.4) | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500221; called by muse, mutect2, varscan2
- NRK | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV54588712, COSV99688277; called by muse, mutect2, varscan2
- NRK | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV54594332; called by muse, mutect2, varscan2
- NRXN2 | c.2894T>A p.F965Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV55451563; called by muse, mutect2, varscan2
- NUP205 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53657938; called by muse, mutect2, varscan2
- OGT | c.2589+1G>T p.X863_splice | Splice Site (SNP) | VAF 52/260 reads (20%) | catalogued as COSV104424950, COSV65480508; called by muse, mutect2, varscan2
- OLFM4 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54576899; called by muse, mutect2, varscan2
- ONECUT1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59948651, COSV59949668; called by muse, varscan2
- OR10AG1 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV56632591; called by muse, mutect2, varscan2
- OR10G9 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 154/756 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs756357322, COSV66686121, COSV66686718; called by muse, mutect2, varscan2
- OR10J3 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV59954180; called by muse, mutect2, varscan2
- OR10K2 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557860396, COSV59221059; called by muse, mutect2
- OR2T34 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 208/2008 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV60900244; called by muse, mutect2, varscan2
- OR2T6 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63216093; called by muse, mutect2, varscan2
- OR4A5 | c.702G>T p.L234F | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV60522282; called by muse, mutect2, varscan2
- OR52N4 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 177/681 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV57890912; called by muse, mutect2, varscan2
- OR56A3 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 241/581 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV61568934; called by muse, mutect2, varscan2
- OR5B21 | c.808del p.I270* | Frame Shift Del (DEL) | VAF 121/722 reads (17%) | catalogued as COSV100835143; called by mutect2, pindel, varscan2
- OR6C70 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV59244771; called by muse, mutect2, varscan2
- OR6Y1 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV56929141; called by muse, mutect2, varscan2
- OR7E24 | c.925A>G p.S309G | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV71702190; called by muse, mutect2, varscan2
- OR8D1 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV63442075; called by muse, mutect2, varscan2
- OR8H2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 146/728 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs777087856, COSV57944234; called by muse, mutect2, varscan2
- OR8K3 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57131306, COSV57132387; called by muse, mutect2, varscan2
- OS9 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57782660; called by muse, mutect2, varscan2
- OSBP | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802800; called by muse, mutect2, varscan2
- OTOP1 | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56392567; called by muse, mutect2, varscan2
- OVOL2 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53860036; called by muse, mutect2, varscan2
- PAK5 | c.1282T>C p.S428P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV62025765; called by muse, mutect2, varscan2
- PBLD | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53265720; called by muse, mutect2
- PCDH11X | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV53459062; called by muse, mutect2, varscan2
- PCDHA4 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs1286163937, COSV63540610, COSV63545846; called by muse, mutect2, varscan2
- PCDHB14 | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV53387962; called by muse, mutect2, varscan2
- PCDHB16 | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.089); catalogued as COSV53361166; called by muse, mutect2, varscan2
- PCLO | c.11341C>T p.R3781* | Nonsense Mutation (SNP) | VAF 28/281 reads (10%) | catalogued as rs865939646, COSV61646028; called by muse, mutect2, varscan2
- PDE11A | c.2671C>G p.L891V | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53692322; called by muse, mutect2, varscan2
- PDE1C | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.034); catalogued as rs773496943, COSV58511052, COSV58511393; called by muse, mutect2, varscan2
- PDE1C | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.161); catalogued as COSV58511412; called by muse, mutect2, varscan2
- PDHX | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV57165605; called by muse, mutect2, varscan2
- PDYN | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54101576, COSV54102606; called by muse, mutect2, varscan2
- PFKFB1 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 36/181 reads (20%) | PolyPhen benign (0.184); catalogued as COSV66628146; called by muse, mutect2, varscan2
- PFKFB1 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 36/180 reads (20%) | PolyPhen benign (0.014); catalogued as COSV66628149; called by muse, mutect2, varscan2
- PHEX | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV65075046; called by muse, mutect2, varscan2
- PI3 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54783135; called by muse, mutect2, varscan2
- PIGO | c.-1-1G>T | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53053397; called by muse, mutect2, varscan2
- PIK3CG | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV63245630; called by muse, mutect2, varscan2
- PIK3R4 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63240476; called by muse, mutect2, varscan2
- PKDREJ | c.1246C>A p.L416M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV53548752; called by muse, mutect2, varscan2
- PKHD1 | c.5567C>A p.S1856* | Nonsense Mutation (SNP) | VAF 64/532 reads (12%) | catalogued as COSV61871639; called by muse, mutect2, varscan2
- PNPLA3 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53377982; called by muse, mutect2, varscan2
- PPP1R12C | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54737031; called by muse, mutect2, varscan2
- PPP1R9A | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV56889907; called by muse, mutect2, varscan2
- PTCHD3 | c.416G>A p.W139* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV71256698; called by muse, varscan2
- PTPN13 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV57406128; called by muse, mutect2, varscan2
- PTPRR | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV51730190; called by muse, mutect2, varscan2
- PTPRT | c.3858G>T p.Q1286H | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61975877; called by muse, mutect2, varscan2
- PXDN | c.3521G>T p.R1174M | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99412744; called by muse, mutect2, varscan2
- PXDNL | c.2009A>T p.Q670L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62485829; called by mutect2, varscan2
- RAB19 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52044433; called by muse, mutect2, varscan2
- RANBP2 | c.4373A>G p.K1458R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV51699843; called by muse, mutect2, varscan2
- RAPGEF6 | c.1320A>G p.I440M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57244719; called by muse, mutect2, varscan2
- RASAL3 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59139193; called by mutect2, varscan2
- RCOR2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56849938; called by muse, mutect2, varscan2
- RETSAT | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV55525207, COSV55525699; called by muse, mutect2, varscan2
- RFTN2 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV54387879; called by muse, mutect2, varscan2
- RFX4 | c.831C>A p.D277E (on ENST00000392842 / NM_213594.3; = p.D183E on NM_032491.6) | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.935); catalogued as COSV57575122; called by muse, mutect2, varscan2
- RHOBTB1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100558374; called by mutect2, varscan2
- RPLP0 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1224580367, COSV56106725; called by muse, mutect2, varscan2
- RPLP0 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56106732; called by muse, mutect2, varscan2
- RPS6KA6 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1347850032, COSV53118780; called by muse, mutect2, varscan2
- RPTN | c.2347C>A p.Q783K | Missense Mutation (SNP) | VAF 598/3095 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV60167045; called by muse, mutect2, varscan2
- RPUSD4 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV53599197; called by muse, mutect2, varscan2
- RXFP1 | c.545G>C p.S182T | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV57049094; called by muse, varscan2
- RXRG | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1461075815, COSV63231944; called by muse, mutect2, varscan2
- RYR2 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV63680246; called by muse, mutect2, varscan2
- RYR2 | c.1236A>T p.E412D | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV63680247; called by muse, mutect2
- SCEL | c.1066G>T p.V356L (on ENST00000349847 / NM_144777.3; = p.V336L on NM_003843.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV62993324; called by muse, mutect2, varscan2
- SCGB2A1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55276061; called by muse, mutect2, varscan2
- SCN9A | c.4154T>A p.L1385Q (on ENST00000303354; = p.L1374Q on NM_002977.3) | Missense Mutation (SNP) | VAF 56/607 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV57607137; called by muse, mutect2
- SDHAF3 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV64490995; called by muse, mutect2, varscan2
- SERPINC1 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907768931, CM940130, CM952084, COSV62929207; called by muse, mutect2, varscan2
- SETDB1 | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 78/1164 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as COSV54981090; called by muse, mutect2
- SFMBT2 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62808521; called by muse, mutect2, varscan2
- SFMBT2 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100738649, COSV62815777; called by muse, mutect2, varscan2
- SGPL1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV54736721, COSV54736797; called by mutect2, varscan2
- SIGLEC1 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755506229, COSV52462185; called by mutect2, varscan2
- SIPA1L2 | c.4470G>C p.E1490D | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs750413617, COSV53388805; called by muse, mutect2
- SLC24A4 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV54111238; called by muse, mutect2
- SLC38A8 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1387496280, COSV55305948, COSV55305998; called by muse, mutect2, varscan2
- SLC44A4 | c.1461A>C p.L487F | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57666898; called by muse, mutect2, varscan2
- SLC44A5 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV63763130; called by muse, mutect2, varscan2
- SLC4A4 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | catalogued as COSV52622204; called by muse, mutect2, varscan2
- SLCO1A2 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 94/333 reads (28%) | catalogued as COSV56600790; called by muse, mutect2, varscan2
- SLCO1B1 | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57009944; called by muse, mutect2, varscan2
- SLFN5 | c.748A>T p.S250C | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV104410448, COSV55480793; called by muse, mutect2, varscan2
- SLIT2 | c.2598C>A p.N866K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56569200; called by muse, mutect2, varscan2
- SMC6 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV61173636; called by muse, mutect2
- SND1 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 141/468 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61239463; called by muse, mutect2, varscan2
- SNX24 | c.374C>A p.S125* | Nonsense Mutation (SNP) | VAF 74/230 reads (32%) | catalogued as COSV54450796; called by muse, varscan2
- SORBS1 | c.1054G>A p.G352S (on ENST00000361941 / NM_001034954.2; = p.G188S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV53356326; called by muse, mutect2, varscan2
- SPANXN1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 91/507 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV65122266; called by muse, mutect2, varscan2
- SPTA1 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs771093658, COSV63751987; called by muse, mutect2, varscan2
- STC1 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV51688262; called by muse, mutect2, varscan2
- STRN3 | c.1765G>T p.V589F (on ENST00000357479 / NM_001083893.2; = p.V505F on NM_014574.4) | Missense Mutation (SNP) | VAF 143/511 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62579257; called by muse, mutect2, varscan2
- STT3A | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV67064591; called by muse, mutect2, varscan2
- STX16 | c.620A>T p.D207V (on ENST00000371141 / NM_001001433.3; = p.D186V on NM_003763.6) | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56605163; called by muse, mutect2, varscan2
- STXBP3 | c.684+1G>C p.X228_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV64182050; called by mutect2, varscan2
- STYXL2 | c.3446G>T p.R1149M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV54804204; called by muse, mutect2, varscan2
- SUPT7L | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV58134538; called by muse, mutect2
- SYNE1 | c.14811C>G p.S4937R (on ENST00000367255 / NM_182961.4; = p.S4866R on NM_033071.3) | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54961884; called by muse, mutect2, varscan2
- SYNE1 | c.14810G>A p.S4937N (on ENST00000367255 / NM_182961.4; = p.S4866N on NM_033071.3) | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs756252126, COSV54961936; called by muse, mutect2, varscan2
- SYNE1 | c.4480G>A p.E1494K (on ENST00000367255 / NM_182961.4; = p.E1501K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54930382; called by muse, mutect2
- SYTL2 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100313827, COSV100314544; called by muse, mutect2, varscan2
- SYTL2 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV60358307; called by muse, mutect2, varscan2
- TAAR1 | c.475A>C p.I159L | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as COSV51588466, COSV51588641; called by muse, mutect2, varscan2
- TAF1 | c.3067C>T p.P1023S (on ENST00000373790 / NM_138923.4; = p.P1044S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV52111680; called by muse, mutect2, varscan2
- TBC1D12 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV56553673; called by muse, mutect2, varscan2
- TBX5 | c.1148del p.S383Lfs*11 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | catalogued as COSV59865898; called by mutect2, varscan2
- TENM1 | c.4083+1G>T p.X1361_splice | Splice Site (SNP) | VAF 130/655 reads (20%) | catalogued as COSV64430336; called by muse, mutect2, varscan2
- TENM1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 116/713 reads (16%) | catalogued as COSV64430349; called by muse, varscan2
- TENM4 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53623121; called by muse, mutect2
- TEX13A | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV61153300; called by muse, mutect2, varscan2
- TEX13A | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100780917, COSV61157268; called by muse, mutect2
- TFCP2L1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV99747892; called by muse, mutect2, varscan2
- TG | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as COSV55070588; called by muse, mutect2, varscan2
- TIMM21 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50053604; called by muse, mutect2, varscan2
- TJP1 | c.5206G>T p.V1736F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369915729; called by muse, mutect2, varscan2
- TLR1 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | catalogued as COSV58304033; called by muse, mutect2, varscan2
- TMEM108 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 230/1133 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV58869867; called by muse, mutect2, varscan2
- TMEM132D | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV67159961; called by muse, mutect2, varscan2
- TMEM72 | c.95C>G p.T32S | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67460415; called by muse, mutect2, varscan2
- TNKS | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60055937; called by muse, mutect2, varscan2
- TNN | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 95/466 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1369127221, COSV53425053; called by muse, mutect2, varscan2
- TNR | c.2279G>C p.R760P | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54868243, COSV54881171; called by muse, mutect2, varscan2
- TOP2A | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV101396101; called by mutect2, varscan2
- TRAM1 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51597827; called by muse, mutect2, varscan2
- TRIP13 | c.593T>G p.I198S | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51319723; called by muse, mutect2, varscan2
- TSGA10 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs376022194, COSV61822998; called by mutect2, varscan2
- TSN | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.285); catalogued as COSV101067462, COSV67605260; called by muse, mutect2, varscan2
- TSNARE1 | c.1118G>T p.R373M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100210052; called by muse, mutect2, varscan2
- TTC21B | c.2207T>C p.L736P | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV54629770; called by muse, mutect2
- TTLL2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs547856286, COSV53443496; called by muse, mutect2, varscan2
- TTN | c.97371C>G p.I32457M (on ENST00000591111; = p.I25033M on NM_003319.4) | Missense Mutation (SNP) | VAF 23/255 reads (9%) | PolyPhen benign (0.318); catalogued as COSV60000672; called by muse, mutect2
- TTN | c.60017C>A p.T20006K (on ENST00000591111; = p.T12582K on NM_003319.4) | Missense Mutation (SNP) | VAF 52/557 reads (9%) | PolyPhen benign (0.036); catalogued as COSV60000709; called by muse, mutect2
- UGCG | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046942237, COSV65335804, COSV65336106; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4331T>C p.L1444P | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54436279; called by muse, mutect2, varscan2
- UMODL1 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61159862; called by muse, mutect2, varscan2
- UNC5D | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 110/744 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54788068; called by muse, mutect2, varscan2
- VAX2 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs782217454, COSV52265708, COSV99313382; called by muse, mutect2, varscan2
- VIRMA | c.4162A>T p.K1388* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52584267; called by mutect2, varscan2
- VRTN | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV56440426; called by muse, mutect2, varscan2
- VSIG4 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV66073596; called by muse, mutect2, varscan2
- WNK3 | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV63613298; called by muse, mutect2, varscan2
- WRN | c.3107A>G p.K1036R | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as rs773176431, COSV53299117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPNPEP2 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV100941441; called by muse, mutect2, varscan2
- ZBTB49 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV61924879; called by muse, mutect2
- ZFP69 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65528865; called by muse, mutect2
- ZFR | c.1979+1G>A p.X660_splice | Splice Site (SNP) | VAF 83/259 reads (32%) | catalogued as COSV54052376; called by muse, mutect2, varscan2
- ZFYVE26 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as COSV61327394; called by muse, mutect2, varscan2
- ZFYVE26 | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61327412, COSV61328947; called by muse, mutect2
- ZIC3 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV54973692; called by muse, mutect2, varscan2
- ZNF208 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV68104067; called by muse, mutect2, varscan2
- ZNF33A | c.2332G>T p.E778* (on ENST00000458705 / NM_006974.3; = p.E779* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 39/235 reads (17%) | catalogued as COSV56724472; called by muse, mutect2, varscan2
- ZNF536 | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV62822732; called by muse, mutect2, varscan2
- ZNF592 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55436319; called by muse, mutect2, varscan2
- ZNF638 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV52485577, COSV52493184; called by muse, mutect2, varscan2
- ZNF711 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52153293; called by muse, mutect2, varscan2
- ZNF713 | c.944C>G p.S315C (on ENST00000633730 / NM_001366796.2; = p.S328C on NM_182633.3) | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV70056639; called by muse, mutect2, varscan2
- ZP4 | c.1601G>C p.C534S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63910959, COSV63911734; called by muse, mutect2, varscan2
- ZSCAN25 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV53552798; called by muse, mutect2
- AFF4 | c.3241_3244del p.S1081Qfs*2 | Frame Shift Del (DEL) | VAF 35/72 reads (49%) | called by mutect2, pindel, varscan2
- AGTR2 | c.474del p.W158Cfs*6 | Frame Shift Del (DEL) | VAF 148/988 reads (15%) | called by mutect2, pindel, varscan2
- AKAP7 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2
- ANKRD6 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- C8orf34 | c.425_443del p.Q142Lfs*29 | Frame Shift Del (DEL) | VAF 29/220 reads (13%) | called by mutect2, pindel
- GDPD1 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- IGKV1D-43 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGKV5-2 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RAPL2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 32/652 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.301); called by muse, mutect2
- KCNMA1 | c.3124G>T p.V1042F (on ENST00000286628 / NM_001161352.2; = p.V984F on NM_002247.4) | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAPTM4A | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- LCE3A | c.115_123del p.C39_P41del | In Frame Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MAGEE1 | c.2359del p.L787* | Frame Shift Del (DEL) | VAF 64/257 reads (25%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.3255del p.H1085Qfs*21 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- MTOR | c.3863G>T p.S1288I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NBPF9 | c.1333G>C p.V445L | Missense Mutation (SNP) | VAF 267/1005 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- NOS1 | c.3078del p.S1027Afs*23 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- POP1 | c.297del p.K100Sfs*3 | Frame Shift Del (DEL) | VAF 53/312 reads (17%) | called by mutect2, pindel, varscan2
- PYCARD | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.3804_3805insAA p.E1269Kfs*3 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- SCUBE2 | c.3031T>C p.S1011P (on ENST00000649792 / NM_001367977.2; = p.S954P on NM_020974.3) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SF3A1 | c.654C>T p.I218= | Splice Region (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- TRAV7 | c.223_225delinsT p.G75Lfs*2 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | called by pindel, varscan2*
- UTRN | c.7836_7839dup p.Y2614Rfs*17 | Frame Shift Ins (INS) | VAF 47/243 reads (19%) | called by mutect2, varscan2
- VWF | c.6766C>G p.Q2256E | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- ZFC3H1 | c.2641del p.I881Ffs*9 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.1976-1G>A p.X659_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- ZNF343 | c.53del p.L18Cfs*9 | Frame Shift Del (DEL) | VAF 25/213 reads (12%) | called by mutect2, pindel, varscan2
- ACTL9 | c.564C>T p.H188= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV61005582; called by muse, mutect2, varscan2
- ANK2 | c.360A>T p.G120= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV52157157; called by muse, mutect2, varscan2
- AQP8 | c.612G>T p.V204= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV54844982, COSV99563755; called by muse, mutect2, varscan2
- ARMCX2 | c.345C>A p.A115= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV57529787; called by muse, mutect2, varscan2
- ARMCX3 | c.84T>C p.T28= | Silent (SNP) | VAF 72/318 reads (23%) | catalogued as COSV57870193; called by muse, varscan2
- ASTN2 | c.3699G>A p.L1233= (on ENST00000313400 / NM_001365069.1; = p.L1182= on NM_014010.5) | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as COSV56003198, COSV99940429; called by muse, mutect2, varscan2
- ATP8B2 | c.1876C>T p.L626= (on ENST00000672630; = p.L593= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV59245699; called by muse, mutect2, varscan2
- BRD9 | c.1257G>T p.V419= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as COSV60246176; called by muse, mutect2
- BRF1 | c.366G>T p.L122= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV59268093; called by muse, mutect2, varscan2
- C1R | c.807A>T p.L269= (on ENST00000536053 / NM_001354346.2; = p.L255= on NM_001733.7) | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as COSV73293798; called by muse, mutect2, varscan2
- C9 | c.1344C>A p.T448= | Silent (SNP) | VAF 76/518 reads (15%) | catalogued as rs1366887364, COSV54677385, COSV99661865; called by muse, mutect2, varscan2
- CACNA1E | c.1090C>A p.R364= | Silent (SNP) | VAF 82/385 reads (21%) | catalogued as COSV100701529, COSV62390108; called by muse, mutect2, varscan2
- CACNA2D4 | c.846C>T p.Y282= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV54948722; called by muse, mutect2, varscan2
- CALCR | c.30G>A p.L10= | Silent (SNP) | VAF 72/353 reads (20%) | catalogued as COSV64007498; called by muse, mutect2, varscan2
- CCDC150 | c.2568C>T p.A856= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV55873745; called by muse, mutect2, varscan2
- CCNB3 | c.3153C>A p.P1051= | Silent (SNP) | VAF 76/231 reads (33%) | catalogued as COSV99328687, COSV99329215; called by muse, mutect2, varscan2
- CDH18 | c.2160G>T p.L720= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV56916371; called by muse, mutect2, varscan2
- CDH8 | c.1461G>A p.L487= | Silent (SNP) | VAF 80/297 reads (27%) | catalogued as COSV54861977, COSV54901567; called by muse, mutect2, varscan2
- CDHR1 | c.1533C>A p.T511= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV60561632; called by muse, mutect2, varscan2
- CHRM2 | c.993C>G p.T331= | Silent (SNP) | VAF 60/230 reads (26%) | catalogued as COSV57770006; called by muse, mutect2, varscan2
- CLPTM1 | c.696G>T p.V232= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV61611678; called by muse, mutect2, varscan2
- CTNND1 | c.114G>T p.S38= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV100649935, COSV62386736; called by muse, mutect2, varscan2
- CYSLTR2 | c.520C>T p.L174= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV56165632; called by muse, mutect2, varscan2
- DCAF8L1 | c.1005C>A p.V335= | Silent (SNP) | VAF 63/194 reads (32%) | catalogued as COSV71595240; called by muse, mutect2, varscan2
- DCAF8L1 | c.603C>A p.T201= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV71595242; called by mutect2, varscan2
- DDX53 | c.1797A>T p.V599= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV60068884; called by muse, mutect2, varscan2
- DLGAP1 | c.1746C>T p.S582= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as COSV59798749; called by muse, mutect2, varscan2
- DOCK9 | c.4143G>T p.S1381= (on ENST00000376460 / NM_001366676.2; = p.S1382= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100237360, COSV100238397; called by muse, mutect2, varscan2
- DYNC1H1 | c.5490T>C p.I1830= | Silent (SNP) | VAF 76/270 reads (28%) | catalogued as COSV64136267; called by muse, mutect2, varscan2
- FARP1 | c.3039C>T p.S1013= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs1376770800, COSV60330215; called by muse, mutect2, varscan2
- GAL3ST1 | c.462G>A p.P154= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs746563784, COSV58892382; called by muse, mutect2, varscan2
- GNAS | c.222A>G p.E74= | Silent (SNP) | VAF 26/378 reads (7%) | catalogued as COSV55671776, COSV55674711; called by muse, mutect2
- GPRASP1 | c.75G>T p.G25= | Silent (SNP) | VAF 97/414 reads (23%) | catalogued as COSV64355407; called by muse, mutect2, varscan2
- GZMB | c.66C>T p.I22= | Silent (SNP) | VAF 30/246 reads (12%) | catalogued as rs139103546; called by muse, mutect2, varscan2
- HCN1 | c.2341C>A p.R781= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100299291, COSV100303082; called by muse, mutect2, varscan2
- HRNR | c.7341T>C p.R2447= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs1323241166, COSV100913132; called by mutect2, varscan2
- HUWE1 | c.10581C>T p.V3527= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs369048914, COSV53342728; called by muse, mutect2, varscan2
- ICE1 | c.4446G>A p.E1482= | Silent (SNP) | VAF 166/434 reads (38%) | catalogued as rs566445452, COSV56823022; called by muse, mutect2, varscan2
- IL18R1 | c.360C>T p.F120= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs750592389, COSV52124073, COSV52127118; called by muse, mutect2, varscan2
- IL26 | c.111A>C p.T37= | Silent (SNP) | VAF 289/1235 reads (23%) | catalogued as COSV57488794; called by muse, varscan2
- IL7R | c.372C>A p.T124= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV100285999, COSV57407753; called by muse, mutect2, varscan2
- ISLR | c.1068G>A p.G356= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV51433522; called by muse, mutect2
- KIF2B | c.714C>A p.V238= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV52129551, COSV52133682; called by muse, mutect2, varscan2
- KLHL28 | c.363G>T p.L121= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV61887937; called by muse, mutect2, varscan2
- LHCGR | c.816G>T p.T272= | Silent (SNP) | VAF 90/319 reads (28%) | catalogued as COSV54296037; called by muse, mutect2, varscan2
- LHFPL1 | c.75C>A p.T25= | Silent (SNP) | VAF 217/1176 reads (18%) | catalogued as COSV64333288; called by muse, mutect2, varscan2
- LHX4 | c.258C>A p.G86= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV55374810, COSV55378519; called by muse, mutect2, varscan2
- LILRB1 | c.1977C>A p.A659= (on ENST00000427581; = p.A608= on NM_006669.6) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV61117428; called by muse, mutect2, varscan2
- LRBA | c.7200A>G p.S2400= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs1456691130, COSV63953568; called by muse, mutect2, varscan2
- LRP2 | c.600T>C p.Y200= | Silent (SNP) | VAF 47/390 reads (12%) | catalogued as COSV55550084; called by muse, mutect2, varscan2
- LRRIQ4 | c.249G>T p.L83= | Silent (SNP) | VAF 163/235 reads (69%) | catalogued as COSV61619003; called by muse, mutect2, varscan2
- LRRIQ4 | c.1287G>A p.R429= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as rs774639573, COSV61619009; called by muse, mutect2, varscan2
- MAP10 | c.1953G>T p.L651= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV69363389; called by muse, mutect2, varscan2
- MOSPD1 | c.501G>T p.V167= | Silent (SNP) | VAF 70/405 reads (17%) | catalogued as COSV66189269; called by muse, mutect2, varscan2
- MS4A5 | c.34C>T p.L12= | Silent (SNP) | VAF 14/445 reads (3%) | called by muse, mutect2
- MUSK | c.1473A>G p.T491= | Silent (SNP) | VAF 130/383 reads (34%) | catalogued as COSV51883803; called by muse, mutect2, varscan2
- MXRA5 | c.4938G>A p.P1646= | Silent (SNP) | VAF 80/420 reads (19%) | catalogued as rs138419461, COSV54232324; called by muse, mutect2, varscan2
- NALCN | c.1617G>T p.T539= | Silent (SNP) | VAF 41/214 reads (19%) | catalogued as COSV51930762; called by muse, mutect2, varscan2
- NRK | c.1167C>A p.P389= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV99687001; called by muse, mutect2, varscan2
- NRXN1 | c.468G>T p.G156= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV68004020; called by muse, mutect2, varscan2
- OR1C1 | c.774C>G p.V258= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as COSV68715660; called by muse, mutect2, varscan2
- OR1K1 | c.690C>A p.P230= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52956468; called by muse, mutect2, varscan2
- OR2T6 | c.48G>T p.G16= | Silent (SNP) | VAF 64/242 reads (26%) | catalogued as COSV63216090; called by muse, mutect2
- OVGP1 | c.324C>A p.T108= | Silent (SNP) | VAF 30/399 reads (8%) | catalogued as COSV63858232; called by muse, mutect2
- PLP1 | c.426G>A p.L142= | Silent (SNP) | VAF 187/751 reads (25%) | catalogued as COSV58276290; called by muse, mutect2, varscan2
- PRG4 | c.2526T>A p.P842= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV63355294; called by muse, mutect2, varscan2
- PRKD3 | c.42A>G p.V14= | Silent (SNP) | VAF 24/207 reads (12%) | catalogued as COSV52212666; called by muse, mutect2, varscan2
- PRRG3 | c.510G>T p.R170= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV64850961; called by muse, varscan2
- PTBP3 | c.243A>G p.P81= | Silent (SNP) | VAF 64/189 reads (34%) | catalogued as rs1156493219, COSV52957011; called by muse, mutect2, varscan2
- RBBP9 | c.231G>A p.G77= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV61499852; called by muse, mutect2, varscan2
- RBM26 | c.1098G>A p.P366= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs367759226; called by muse, varscan2
- RBM45 | c.408G>A p.L136= | Silent (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- RHBG | c.1194T>C p.F398= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV54803883; called by muse, mutect2, varscan2
- RIC1 | c.2136A>G p.V712= | Silent (SNP) | VAF 60/211 reads (28%) | catalogued as rs777849861, COSV52608638; called by muse, mutect2, varscan2
- RIF1 | c.6864A>G p.T2288= | Silent (SNP) | VAF 88/353 reads (25%) | catalogued as COSV54615879; called by muse, mutect2, varscan2
- SLC1A7 | c.612G>T p.P204= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV65195037; called by muse, mutect2, varscan2
- SLC2A14 | c.891C>A p.S297= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs747868865, COSV61586287; called by muse, mutect2, varscan2
- SNAP91 | c.516G>A p.Q172= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV52120484; called by muse, mutect2, varscan2
- SPATA31A1 | c.2049C>A p.S683= | Silent (SNP) | VAF 38/337 reads (11%) | called by muse, mutect2
- SPTA1 | c.375C>A p.A125= | Silent (SNP) | VAF 92/451 reads (20%) | catalogued as COSV63751992; called by muse, mutect2, varscan2
- SYTL5 | c.162G>T p.G54= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs1215722683, COSV52900235; called by muse, varscan2
- TET1 | c.5319G>T p.V1773= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV65384141; called by muse, mutect2, varscan2
- TFAP2D | c.1338C>A p.G446= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV50413124; called by muse, mutect2, varscan2
- TMEM132E | c.1026G>C p.T342= (on ENST00000321639; = p.T432= on NM_001304438.2) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs774833623, COSV58696331, COSV58696905; called by muse, mutect2, varscan2
- TMEM132E | c.1350C>T p.H450= (on ENST00000321639; = p.H540= on NM_001304438.2) | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV58696340; called by muse, mutect2, varscan2
- TRIML2 | c.837T>C p.D279= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV58715693; called by muse, mutect2
- TTLL4 | c.537A>C p.T179= | Silent (SNP) | VAF 70/273 reads (26%) | catalogued as COSV51436032; called by muse, mutect2, varscan2
- UGGT1 | c.3585C>T p.I1195= | Silent (SNP) | VAF 60/476 reads (13%) | catalogued as rs754717348; called by muse, mutect2, varscan2
- UTP14A | c.1387C>T p.L463= | Silent (SNP) | VAF 99/422 reads (23%) | catalogued as COSV64086721; called by muse, mutect2, varscan2
- UTP14A | c.1803G>T p.G601= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV64086723; called by muse, mutect2, varscan2
- UTRN | c.6417G>T p.L2139= | Silent (SNP) | VAF 68/270 reads (25%) | catalogued as COSV62333267; called by muse, mutect2, varscan2
- VNN2 | c.1485C>A p.T495= | Silent (SNP) | VAF 38/296 reads (13%) | catalogued as COSV58472297; called by muse, mutect2, varscan2
- YOD1 | c.327C>T p.D109= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1223102759; called by muse, mutect2, varscan2
- ZC2HC1C | c.195G>A p.L65= | Silent (SNP) | VAF 114/596 reads (19%) | catalogued as COSV53172350; called by muse, mutect2, varscan2
- ZNF567 | c.1503A>G p.G501= (on ENST00000536254 / NM_001322913.1; = p.G470= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as COSV62445023; called by muse, mutect2, varscan2
- ZNF777 | c.2127G>T p.L709= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV56097223; called by muse, mutect2, varscan2
- ZNF783 | c.537G>T p.L179= | Silent (SNP) | VAF 64/454 reads (14%) | catalogued as COSV65185242; called by muse, mutect2, varscan2
- ZNF804A | c.1884A>G p.E628= | Silent (SNP) | VAF 124/523 reads (24%) | catalogued as COSV56445379; called by muse, mutect2, varscan2
- AC244258.1 | n.256C>A | RNA (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- AC244258.1 | n.257C>A | RNA (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- AC244258.1 | n.524C>A | RNA (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- ADARB2 | c.1865-1484T>A | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- C1orf220 | n.522G>T | RNA (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- C7orf66 | n.138G>T | RNA (SNP) | VAF 50/291 reads (17%) | called by muse, mutect2, varscan2
- CCNQP1 | n.336C>G | RNA (SNP) | VAF 27/139 reads (19%) | catalogued as rs765464750; called by muse, mutect2, varscan2
- FYB1 | c.1907+1697_1907+1699del | Intron (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- KCNIP4 | c.62-421192C>G | Intron (SNP) | VAF 22/96 reads (23%) | catalogued as COSV66169561; called by muse, mutect2, varscan2
- MBD1 | c.*70A>G | 3'UTR (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99495785; called by muse, mutect2, varscan2
- NACA | c.70+3511C>T | Intron (SNP) | VAF 38/214 reads (18%) | catalogued as COSV100771171; called by muse, mutect2, varscan2
- PIKFYVE | c.322+307C>T | Intron (SNP) | VAF 33/173 reads (19%) | catalogued as COSV100010126; called by muse, mutect2, varscan2
- PTGER3 | c.1077+37C>G | Intron (SNP) | VAF 59/226 reads (26%) | catalogued as COSV100138510, COSV60695739; called by muse, mutect2, varscan2
- SERPINA13P | n.274G>A | RNA (SNP) | VAF 10/45 reads (22%) | catalogued as rs976775507; called by muse, mutect2, varscan2
- SNORD113-3 | n.67G>A | RNA (SNP) | VAF 99/351 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-23 | n.54T>A | RNA (SNP) | VAF 15/125 reads (12%) | called by muse, varscan2
- TMPRSS11F | c.1015+2102C>A | Intron (SNP) | VAF 319/1024 reads (31%) | catalogued as COSV100678303, COSV62466031; called by muse, mutect2, varscan2
- TPH2 | c.609-10876G>T | Intron (SNP) | VAF 41/257 reads (16%) | catalogued as COSV100421966; called by muse, mutect2, varscan2
